Somatic mutation profile of tumor specimen BLGSP-71-08-00028-01A (aliquot BLGSP-71-08-00028-01A-01D-A663-33) from CGCI case BLGSP-71-08-00028, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.7 years (2,430 days).
Specimen BLGSP-71-08-00028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Mandible; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f21c1bc1-461c-40de-a209-f7abcd673921.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00028-10A (Blood Derived Normal), aliquot BLGSP-71-08-00028-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecc77b17-c1c4-4112-8f73-c700793642e2

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTX1 | c.-47C>G | 5'UTR (SNP) | VAF 22/50 reads (44%) | catalogued as rs1397831429, COSV57500390, COSV57501724; called by muse, mutect2, varscan2
